TCGA case TCGA-CN-6998 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/039788ec-1364-40c7-9e9d-13dc305674e9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Dead; Days to death: 357 days.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 53.2 years (19,447 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T3; AJCC pathologic N: N2b; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 2; Lymph nodes tested: 26; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 63 days; Days to treatment end: 141 days; Treatment dose: 6,840 cGy; Treatment outcome: Progressive Disease; Number of fractions: 38; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 64 days; Days to treatment end: 131 days; Treatment outcome: Progressive Disease.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Tonsil, NOS. Age at diagnosis: 53.9 years (19,691 days); Days to diagnosis: 244 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 265 days; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 46 days; Disease response: Tumor Free.
- Day 244 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Tonsil, NOS; Days to recurrence: 244 days.
- Days to follow up: 357 days; Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A: Negative.
- EGFR amplification: Amplified.
- Involved Tissue, NOS human papillomavirus (ISH): Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 40; Tobacco smoking onset year: 1970.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CN-6998-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.7.
  Slide TCGA-CN-6998-01A-01-BS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 55; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 30.
  Slide TCGA-CN-6998-01A-02-BS2: Section location: Bottom; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60.
- Sample TCGA-CN-6998-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CN-6998-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymph node neck dissection indicator: Yes; Lymphovascular invasion: No; Tobacco smoking history indicator: 2; Alcohol history documented: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; New tumor event site: Oropharynx; New tumor event site other: tonsil.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 357 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 357 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 244 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CN-6998-01A-23D-2010-01): tumor purity 0.46, ploidy 4.85, whole-genome doublings 2.
